TARGET case TARGET-15-SJMPAL003414 — Acute Lymphoblastic Leukemia - Phase III (TARGET-ALL-P3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Lymphoid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/92aa6eba-2d43-4b40-9467-305bde60666b

Demographics
Sex at birth: male; Age at index: 5 years; Vital status: Dead; Days to death: 20 days.

Diagnoses (1)
1. Acute lymphocytic leukemia: ICD-O-3 morphology code: 9835/3; ICD-10 code: C91.0; Tissue or organ of origin: Bone marrow; Classification of tumor: primary; Age at diagnosis: 5.3 years (1,943 days); Year of diagnosis: 1993; Days to last follow up: 20 days.

Follow-up (1 entry)
- Days to follow up: 20 days; First event: Relapse; Year of follow up: 1993.

Biospecimens (2 samples)
- Samples TARGET-15-SJMPAL003414-04A, TARGET-15-SJMPAL003414-04A.1 (2 with the same recorded description): Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_ALL_ClinicalData_Phase_III_20230725.xlsx:
- Overall Survival Time in Days: 20
- Protocol: St. Jude
- Initial Therapy: ALL
- Karyotype: 46,XY,t(5;7)(q13.3;p13)[17]/46,XY[3]
- WHO ALAL Classification: T/M
- WHO Dx: T-ALL
- WHO RL1: T/M
